FM case AD8736 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/53d2f548-1b3e-4f1a-9d3b-4dc32fc10c90

Female, 68.9 years: Pheochromocytoma, NOS (ICD-O-3 8700/0) of the adrenal gland; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
